Gene-level copy-number profile of tumor specimen TCGA-86-7955-01A from TCGA case TCGA-86-7955, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 62.3 years (22,772 days).
Specimen TCGA-86-7955-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.c588966f-9011-4e53-a395-87be6f187b37.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-7955-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9325644f-6bd0-4590-8214-a6a22ee0171f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 883; copy number 2: 20,264; copy number 3: 19,998; copy number 4: 10,918; copy number 5: 5,176; copy number 6: 1,564; copy number 7: 491; copy number 8: 3; copy number 9: 456; copy number 10: 35; copy number 11: 17; copy number 14: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-7955-01A-11D-2183-01): tumor purity 0.73, ploidy 3.16, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,011 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,600,851–151,327,715, 41 genes, copy number 7: ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6, CTXND2, CYCSP51, SETDB1, CERS2, AL590133.2, AL590133.1, ANXA9, MINDY1, PRUNE1, RNU6-884P, BNIPL, C1orf56, CDC42SE1, MLLT11, GABPB2, RPS29P29, AL592424.1, SEMA6C, TNFAIP8L2, SCNM1, LYSMD1, TMOD4, VPS72, PIP5K1A, PSMD4, ZNF687-AS1, ZNF687, PI4KB, RN7SL444P.
- chr4:100,395,341–101,348,883, 9 genes, copy number 7: EMCN, AC097459.1, LINC01216, LINC01217, LINC01218, PPP3CA, MIR8066, MIR1255A, FLJ20021.
- chr4:128,552,590–128,875,224, 5 genes, copy number 9 (within-gene range 5–9): AC110609.1, AC078850.1, AC078850.2, JADRR, JADE1.
- chr4:129,612,330–132,345,621, 21 genes, copy number 7 (within-gene range 4–7): LINC02466, LINC02465, EEF1GP8, LINC02479, PGBD4P4, GAPDHP56, AC093831.2, AC093831.1, AC093902.1, AC025554.1, RNU6-224P, LINC02377, AC105424.1, RN7SL205P, SNHG27, SNORA70, AC107393.1, RPL7AP28, AC096711.2, AC093916.1, AC096711.1.
- chr4:136,004,509–139,420,033, 46 genes, copy number 9 (within-gene range 5–9): AC104136.1, AC073429.2, AC018680.1, AC073429.1, TERF1P3, AC093875.1, LINC02511, LINC02510, SERF1AP1, STMN1P2, RPS23P2, PCDH18, LINC02172, AC116563.2, AC116563.1, AC131956.2, AC131956.3, AC131956.1, AC097511.1, LINC00616, SLC7A11-AS1, SLC7A11, AC093903.1, LINC00498, LINC00499, LINC00500, AC105416.1, AC098859.1, AC098859.2, AC093766.1, AC109927.1, AC109927.2, NOCT, ELF2, RNU6-531P, RN7SL382P, PPP1R14BP3, Metazoa_SRP, RN7SL311P, Y_RNA, RNU6-506P, RNU6-1074P, MGARP, NDUFC1, NAA15, RNU6-1214P.
- chr4:142,023,160–142,847,432, 1 gene, copy number 7 (within-gene range 5–7): INPP4B.
- chr4:142,317,238–149,278,123, 103 genes, copy number 7 (broad region; genes not listed).
- chr6:46,852,522–47,042,350, 3 genes, copy number 8: ADGRF5, ADGRF5-AS1, ADGRF1.
- chr8:39,522,976–40,520,158, 18 genes, copy number 7 (within-gene range 5–7): AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1.
- chr8:60,289,928–62,249,879, 29 genes, copy number 10 (within-gene range 3–10): LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2, CHD7, AC113143.1, AC113143.2, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1.
- chr8:62,473,217–62,483,811, 2 genes, copy number 10: AC018861.2, AC018861.1.
- chr8:74,798,784–75,034,558, 6 genes, copy number 11: AC011632.1, AC026616.1, PI15, AC011632.2, CRISPLD1, AC100782.1.
- chr8:78,268,637–81,815,714, 78 genes, copy number 9–14 (within-gene range 3–14) (broad region; genes not listed).
- chr8:117,794,490–118,111,826, 1 gene, copy number 10 (within-gene range 3–10): EXT1.
- chr8:127,686,343–127,742,951, 2 genes, copy number 10 (within-gene range 3–10): CASC11, MYC.
- chr8:127,795,962–127,796,028, 1 gene, copy number 10: MIR1204.
- chr8:138,588,235–143,083,001, 84 genes, copy number 7–9 (broad region; genes not listed).
- chr11:99,020,949–112,022,653, 200 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr11:112,029,858–112,036,863, 3 genes, copy number 7: PPIHP1, RNU6-893P, AP000907.3.
- chr14:26,443,090–50,668,306, 346 genes, copy number 9 (broad region; genes not listed).
- chr15:97,572,185–98,293,199, 12 genes, copy number 7 (within-gene range 3–7): LINC00923, AC024651.2, AC024651.3, ARRDC4, AC024651.1, LINC02251, U6, AC022523.1, RNU6-1186P, LINC01582, AC022523.3, AC022523.2.

Autosomal genes at a single copy (total copy number 1): 883. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
